Gene-level copy-number profile of tumor specimen TCGA-52-7809-01A from TCGA case TCGA-52-7809, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.6 years (27,233 days).
Specimen TCGA-52-7809-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2f981e44-acd5-4b82-aab6-88565d22b334.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-52-7809-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 830 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/95a11587-2dad-4327-bb94-8b8a8e39b9a9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 3,007; copy number 2: 26,209; copy number 3: 18,278; copy number 4: 7,549; copy number 5: 2,986; copy number 6: 774; copy number 7: 370; copy number 8: 10; copy number 9: 278; copy number 10: 119; copy number 11: 84; copy number 13: 26; copy number 16: 34; copy number 25: 53.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-52-7809-01A-21D-2121-01): tumor purity 0.52, ploidy 2.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:44,712–942,743, 16 genes: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,700 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–10,914,225, 180 genes, copy number 5–6 (broad region; genes not listed).
- chr2:15,690,782–69,252,364, 904 genes, copy number 5–13 (broad region; genes not listed).
- chr2:75,646,783–75,690,851, 1 gene, copy number 6 (within-gene range 4–6): MRPL19.
- chr2:75,652,000–76,698,996, 17 genes, copy number 6 (within-gene range 4–6): GCFC2, AC005034.3, AC005034.5, AC005034.2, AC005034.6, AC005034.4, AC110614.1, SUCLA2P2, AC073091.1, AC073091.2, PNPP1, USP21P2, RN7SKP203, RN7SKP164, AC068616.2, AC068616.3, AC068616.1.
- chr2:137,512,098–148,021,604, 103 genes, copy number 6 (broad region; genes not listed).
- chr2:148,044,380–148,062,577, 2 genes, copy number 6: AC019226.1, AC019226.2.
- chr3:93,843,764–198,222,513, 1,799 genes, copy number 5–11 (broad region; genes not listed).
- chr5:58,198–55,227,315, 788 genes, copy number 5 (broad region; genes not listed).
- chr5:178,859,953–181,342,213, 111 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:120,273,175–122,310,691, 27 genes, copy number 6 (within-gene range 4–6): KCND2, RNU6-581P, AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, AC006364.1, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2, PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1, FEZF1, FEZF1-AS1.
- chr7:122,328,469–122,440,388, 1 gene, copy number 6 (within-gene range 2–6): AC004594.1.
- chr9:32,886,601–33,076,674, 7 genes, copy number 5 (within-gene range 1–5): APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1.
- chr10:971,146–1,289,426, 7 genes, copy number 8: AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200.
- chr10:1,201,406–1,361,637, 3 genes, copy number 8: AL392083.2, AL392083.1, AL513304.1.
- chr12:66,767–442,642, 13 genes, copy number 5 (within-gene range 3–5): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77.
- chr14:92,703,807–92,748,679, 1 gene, copy number 5: LGMN.
- chr15:19,878,555–24,090,821, 177 genes, copy number 5–13 (broad region; genes not listed).
- chr19:27,638,483–30,872,507, 67 genes, copy number 6 (broad region; genes not listed).
- chr19:31,348,881–40,090,938, 391 genes, copy number 9–11 (broad region; genes not listed).
- chr20:30,214,765–33,354,444, 101 genes, copy number 9–25 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,007. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
